Surgical pathology report (de-identified scan), TCGA case TCGA-GL-A9DD, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site ABS - IUPUI, specimen TCGA-GL-A9DD-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3
Carcinoma, papillary renal cell 826013
Site R Kidney NOS 864.9
Op 3/3/14

Operative Procedure:
Right DA Vinci partial nephrectomy

Specimen Received:
Right renal mass (FS)

Final Pathologic Diagnosis:
Kidney, right, Da Vinci laparoscopic partial nephrectomy:

Tumor histologic type: Papillary renal cell carcinoma, type 1
Sarcomatoid features (%): Not identified
Tumor size: 2.4 cm (greatest dimension)
Other dimensions: 2.3 x 2.3 cm
Macroscopic extent of tumor: Confined to the kidney
Focality: Unifocal
Number of tumors: 1
Fuhrman grade: 2 of 4
Microscopic extent of tumor:
Perinephric fat invasion: Not identified
Renal sinus invasion: Not applicable
Other: Not applicable
Renal vein involvement: Not applicable
Adrenal gland present: No
(If yes) Involved by tumor: Not applicable
(If yes) Direct invasion or metastasis: Not applicable
Cancer at resection margin: No
(If yes) Location(s): Not applicable
Pathologic findings in nonneoplastic kidney: None significant
Hilar lymph nodes present: No
(If yes) Number involved/number present: Not applicable

Pathologic stage (2010) pT1a pNx pM-not applicable

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Intraoperative Consult Diagnosis:

FSA: Right renal mass:
Margin not involved by tumor, gross only.
F/S TAT:

Gross Description:

Received without fixative labeled "right renal mass" is a 3.7 x 3.0 x 2.7 cm partial nephrectomy with minimal adherent perinephric fat. Definitive renal sinus is not identified. The parenchymal margin is previously inked black and perinephric fat green. Sectioning reveals a 2.4 x 2.3 x 2.3 cm

[page 2 of 2]
variegated tan-red to orange, heterogeneous, markedly hemorrhagic well delineated mass that abuts the capsule and comes to within 0.2 cm from the parenchymal margin. The uninvolved parenchyma is tan and homogeneous. A gross photograph is taken.

Representative sections are submitted as follows:

- 1-2 mass to inked parenchymal margin;
- 3-4 mass to capsule;
- 5 uninvolved parenchyma.

Microscopic Description:

The final diagnosis of each specimen incorporates the microscopic examination findings.

END OF REPORT

Surgical Pathology Report

Taken DOB: Gender: M

Source: NCI Genomic Data Commons file 391351be-7384-4b72-8455-979dc7c656de (TCGA-GL-A9DD.B64C5597-E57A-4ED3-9B02-D5A1D3011438.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).